Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A64O, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A64O-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A-C. Cranium, left anterolateral temporal lobe #1, #2 and CUSA. resection: Low grade oligoastrocytoma, astrocytic predominant (WHO grade II).

Seen in consultation with

Immunohistochemical stains were performed on paraffin embedded tissue using antibodies to GFAP, IDH1 (R132H), p53 and Ki67. GFAP is positive in tumor cells, many of them with abundant cytoplasm and processes. IDH1 (R132H) stain is negative. p53 protein is weakly to moderately expressed in tumor cells. Ki67 labeling is low. This immunophenotype supports above diagnosis.

Interpreted by:

Report electronically signed by

Transcribed by

Preliminary Frozen Section Consultation:

A. Cranium, left anterolateral temporal lobe #1, smears: Diffuse glioma, low-grade. Hold over for grading.

Intraoperative cytologic smear(s) interpretation performed by: .

continued next page Page 1 of 2

4-2-05
Oligoastrocytoma, NOS 9382/3
Site path 2 Glioma, temporal lobe C71.2
CSC 4 Brain, supratentorial NOS C71.0
PhD 5/10/13

[page 2 of 2]
Gross Description:

A. Received fresh labeled "left anterior lateral temporal lobe" is a 4.2 x 3.9 x 1.5 cm portion of brain. Smears prepared. All submitted. Grossed by

B. Received fresh labeled "left anterior lateral temporal lobe #2, cranium" is a 2.8 x 1.5 x 1.2 cm portion of brain. Representative sections are submitted for permanent sections only. Grossed by

C. Received fresh within a trap labeled "left brain - collection sock" is a 1.3 x 1.0 x 0.2 cm aggregate of white-tan and red tissue. Representative sections are submitted for permanent sections only. Grossed by

Block Summary:

Part A: Left anterior lateral temporal lobe

- 1 Lt ant lat temporal lobe1
- 2 Lt ant lat temporal lobe2
- 3 Lt ant lat temporal lobe3
- 4 Lt ant lat temporal lobe4
- 5 Lt ant lat temporal lobe5
- 6 Lt ant lat temporal lobe6
- 7 Lt ant lat temporal lobe7

Part B: Left anterior lateral temporal lobe #2 cranium

- 1 #2 Lt ant lat temporal lobe1
- 2 #2 Lt ant lat temporal lobe2
- 3 #2 Lt ant lat temporal lobe3
- 4 #2 Lt ant lat temporal lobe4

Part C: Left brain-Collection sock

- 1 Lt brain collection sock

END OF REPORT

Page 2 of 2

Source: NCI Genomic Data Commons file d068c032-75fd-4bd5-bcb9-6e0fb4d1df15 (TCGA-DB-A64O.67251C0F-7DD0-4736-A614-523DFD359C63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).